Somatic mutation profile of tumor specimen C3N-03939-02 (aliquot CPT0285390006) from CPTAC case C3N-03939, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.8 years (17,835 days).
Specimen C3N-03939-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21fb196b-913c-4cd0-9ce3-d9f5880bec4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03939-31 (Blood Derived Normal), aliquot CPT0285410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69e6e6a6-0a0f-49b0-a6da-465965b33dc7

The open-access MAF lists 67 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 15, Frame Shift Del 2, 5'UTR 2, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AF196969.1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs886039345, CD1512815, CM014179, CM1512813, COSV99339469; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMIGO1 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.491); catalogued as rs1557887964; called by muse, mutect2, varscan2
- ATP8A2 | c.2479G>A p.G827R | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54978655; called by muse, mutect2, varscan2
- BATF2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs149550890; called by muse, mutect2, varscan2
- CALN1 | c.220G>A p.E74K (on ENST00000329008 / NM_001017440.3; = p.E116K on NM_031468.4) | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs1210215066, COSV100204106, COSV100204679; called by muse, mutect2, varscan2
- CEP43 | c.171A>C p.L57F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV62760458; called by muse, mutect2, varscan2
- CHST5 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 57/410 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs906651671; called by muse, mutect2, varscan2
- CIITA | c.2888+1G>A p.X963_splice | Splice Site (SNP) | VAF 49/377 reads (13%) | catalogued as rs372826934, CS930846; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- GDPD2 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 37/198 reads (19%) | catalogued as rs766368991, COSV65531859; called by muse, mutect2, varscan2
- GRIA3 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1369079140, COSV52079624; called by muse, mutect2, varscan2
- IGKJ1 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as rs768964011; called by muse, mutect2, varscan2
- IRF8 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs775730870; called by muse, mutect2, varscan2
- LPIN1 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.011); catalogued as rs377563304; called by muse, mutect2
- MAP3K10 | c.1945C>T p.R649W | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs746603239; called by muse, varscan2
- MUC21 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779399351; called by muse, mutect2, varscan2
- NAALADL1 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs1291606137; called by muse, mutect2, varscan2
- OR6C1 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as rs1483347925; called by muse, mutect2, varscan2
- PDE1C | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs746042793, COSV58510753; called by muse, mutect2, varscan2
- PNMA3 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs782242475, COSV64721743; called by muse, mutect2, varscan2
- RALYL | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.588); catalogued as rs745691095, COSV72818739; called by muse, mutect2, varscan2
- SLC26A5 | c.2021T>C p.V674A | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1358138369; called by muse, mutect2
- SLC9A3 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs139970401; called by muse, mutect2, varscan2
- SOX8 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1439790155; called by mutect2, varscan2
- TEP1 | c.4807G>A p.V1603I | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs370238754; called by muse, mutect2, varscan2
- TRAF1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs141130520; called by muse, mutect2, varscan2
- TSKS | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs746778316; called by muse, mutect2, varscan2
- ZC3H13 | c.2096G>C p.R699P | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.599); catalogued as COSV54450477; called by muse, mutect2, varscan2
- ZNF831 | c.3473C>T p.T1158M | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs759670265, COSV64046267; called by muse, mutect2, varscan2
- ADGRV1 | c.4874A>C p.D1625A | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.241); called by muse, varscan2
- CD93 | c.854G>A p.C285Y | Missense Mutation (SNP) | VAF 42/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD3 | c.3181A>G p.K1061E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DUSP9 | c.717C>G p.N239K | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FSCB | c.646A>T p.T216S | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GFAP | c.241G>C p.A81P | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- IL18R1 | c.706A>C p.N236H | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYH3 | c.3193G>T p.E1065* | Nonsense Mutation (SNP) | VAF 45/339 reads (13%) | called by muse, mutect2, varscan2
- NF1 | c.3788_3789dup p.E1264Kfs*3 | Frame Shift Ins (INS) | VAF 25/195 reads (13%) | called by mutect2, pindel, varscan2
- NRP2 | c.2563_2566del p.E855Rfs*17 (on ENST00000360409 / NM_201266.2; = p.E850Rfs*17 on NM_003872.3) | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | called by mutect2, pindel, varscan2
- PREPL | c.614T>G p.F205C | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); called by mutect2, varscan2
- RETREG1 | c.608T>G p.V203G (on ENST00000306320 / NM_001034850.2; = p.V62G on NM_019000.4) | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SH3RF1 | c.2499G>A p.R833= | Splice Region (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- SLC35E3 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLCO5A1 | c.575G>C p.G192A | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLCO5A1 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SOX8 | c.934del p.A312Rfs*132 | Frame Shift Del (DEL) | VAF 18/175 reads (10%) | called by mutect2, pindel, varscan2
- SSX4 | c.164A>C p.Y55S | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- TMEM61 | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 85/456 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF804A | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ZNF823 | c.530G>T p.G177V (on ENST00000341191 / NM_001297610.2; = p.G133V on NM_017507.2) | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ARHGEF10L | c.2277G>A p.E759= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as rs772427970; called by muse, mutect2, varscan2
- CEL | c.2034C>T p.D678= (on ENST00000673714; = p.D675= on NM_001807.6) | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1208099811; called by muse, varscan2
- CFAP47 | c.786C>T p.F262= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as rs1474210937, COSV52883009; called by muse, mutect2, varscan2
- GABRQ | c.27C>T p.A9= | Silent (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- HCN1 | c.1857C>T p.N619= | Silent (SNP) | VAF 60/306 reads (20%) | catalogued as rs754531784, COSV57495555; called by muse, mutect2, varscan2
- HDGFL1 | c.609C>T p.N203= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs778477453, COSV57751186; called by muse, mutect2, varscan2
- NFIC | c.75C>T p.R25= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as rs769477819; called by muse, mutect2, varscan2
- OR6C68 | c.273G>A p.T91= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs145384583; called by muse, mutect2, varscan2
- PIGT | c.1545G>A p.V515= | Silent (SNP) | VAF 57/294 reads (19%) | called by muse, mutect2, varscan2
- PSMC4 | c.669A>G p.T223= | Silent (SNP) | VAF 36/181 reads (20%) | called by muse, mutect2, varscan2
- QRFPR | c.504G>A p.V168= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- SNTG2 | c.1341C>T p.F447= | Silent (SNP) | VAF 45/221 reads (20%) | catalogued as rs867779769, COSV57966228; called by muse, mutect2, varscan2
- SUPT20HL2 | c.2139C>T p.L713= | Silent (SNP) | VAF 34/218 reads (16%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.858G>A p.T286= (on ENST00000648592; = p.T252= on NM_182973.2) | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs759889003, COSV60225679; called by muse, varscan2
- XCR1 | c.801C>T p.Y267= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as rs769812816, COSV100499521; called by muse, mutect2, varscan2
- ACTG1 | c.-417C>G | 5'UTR (SNP) | VAF 37/151 reads (25%) | catalogued as rs782728008; called by muse, mutect2, varscan2
- ANO4 | c.-71G>A | 5'UTR (SNP) | VAF 23/168 reads (14%) | catalogued as rs573437877, COSV100154094, COSV54606965; called by muse, mutect2, varscan2
- C9orf24 | c.*51_*52del | 3'UTR (DEL) | VAF 17/151 reads (11%) | catalogued as rs1432822619; called by mutect2, pindel, varscan2
